Somatic mutation profile of tumor specimen BA2330D (aliquot aq-BA2330D) from BEATAML1.0 case 2089, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Therapy related myeloid neoplasm; Tissue or organ of origin: Bone marrow; Age at diagnosis: 69.8 years (25,510 days).
Specimen BA2330D: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 32b7ec1d-7150-49ce-96fc-11e1c944a703.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2873D (Solid Tissue Normal), aliquot aq-BA2873D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a19e4e91-7414-4ce9-960e-e0afd0c499e3

The open-access MAF lists 25 somatic variants for this specimen: 13 protein-altering or splice-affecting, 6 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 6, 3'UTR 3, Intron 2, Splice Site 1, Frame Shift Ins 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DNMT3A | c.2645G>A p.R882H | Missense Mutation (SNP) | VAF 15/81 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.067); catalogued as rs147001633, COSV53036153, COSV53040144, COSV53040431; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- IDH1 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 42/175 reads (24%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.03); PolyPhen benign (0.1); catalogued as rs121913499, CM1111831, COSV61615256, COSV61615456, COSV61615649; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.746G>T p.R249M | Missense Mutation (SNP) | VAF 32/168 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as rs587782329, COSV52666526, COSV52668050, COSV52697169, COSV52713804; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, varscan2
- CLDN17 | c.539G>A p.G180D | Missense Mutation (SNP) | VAF 52/253 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.116); catalogued as rs1249719058; called by muse, mutect2, varscan2
- PCDHA1 | c.1883C>T p.T628M | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.946); catalogued as rs781827223, COSV65375604; called by muse, mutect2, varscan2
- BMPR1B | c.902dup p.M301Ifs*21 | Frame Shift Ins (INS) | VAF 41/188 reads (22%) | called by mutect2, pindel, varscan2
- CHD5 | c.3262+1G>A p.X1088_splice | Splice Site (SNP) | VAF 12/53 reads (23%) | called by muse, mutect2, varscan2
- HELZ2 | c.5994T>G p.C1998W (on ENST00000467148 / NM_001037335.2; = p.C1429W on NM_033405.3) | Missense Mutation (SNP) | VAF 50/222 reads (23%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.765); called by muse, varscan2
- MAP4K4 | c.1734C>A p.H578Q (on ENST00000347699 / NM_001242559.2; = p.H547Q on NM_145686.3) | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2
- PPP1R9B | c.1196G>T p.S399I | Missense Mutation (SNP) | VAF 6/152 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.74); called by muse, mutect2
- SPATC1 | c.859A>C p.I287L | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, varscan2
- TNK1 | c.1379C>A p.A460D (on ENST00000576812 / NM_001251902.2; = p.A455D on NM_003985.5) | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.33); called by muse, mutect2
- ZNF749 | c.1509A>T p.K503N | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- EML4 | c.777C>T p.L259= | Silent (SNP) | VAF 8/50 reads (16%) | called by muse, mutect2, varscan2
- FAM222A | c.792C>A p.T264= | Silent (SNP) | VAF 3/26 reads (12%) | called by muse, mutect2
- MROH6 | c.1332G>T p.A444= | Silent (SNP) | VAF 4/40 reads (10%) | called by muse, mutect2
- PHACTR1 | c.1590C>T p.D530= | Silent (SNP) | VAF 29/165 reads (18%) | catalogued as rs376680831; called by muse, mutect2, varscan2
- PRUNE2 | c.1194C>T p.S398= | Silent (SNP) | VAF 40/150 reads (27%) | catalogued as rs755406745; called by muse, mutect2
- TMEM138 | c.297C>A p.V99= | Silent (SNP) | VAF 5/52 reads (10%) | called by muse, mutect2
- COL9A1 | c.*36C>T | 3'UTR (SNP) | VAF 18/106 reads (17%) | catalogued as rs6923452; called by muse, mutect2, varscan2
- EGFL6 | c.*23C>T | 3'UTR (SNP) | VAF 5/38 reads (13%) | called by muse, mutect2, varscan2
- FOXD3 | c.*8C>A | 3'UTR (SNP) | VAF 5/59 reads (8%) | called by muse, mutect2
- LUC7L | c.61+35G>A | Intron (SNP) | VAF 20/106 reads (19%) | catalogued as rs1042122830; called by muse, varscan2
- PLPP7 | c.451+704G>A | Intron (SNP) | VAF 14/62 reads (23%) | called by muse, mutect2, varscan2
- SSPOP | n.3049G>A | RNA (SNP) | VAF 15/84 reads (18%) | catalogued as rs757139227, COSV50486368; called by muse, mutect2, varscan2
